Somatic mutation profile of tumor specimen TCGA-CZ-4863-01A (aliquot TCGA-CZ-4863-01A-01D-1501-10) from TCGA case TCGA-CZ-4863, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 51.3 years (18,730 days).
Specimen TCGA-CZ-4863-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96918a94-8fc3-4308-8496-7e990f775d03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-4863-11A (Solid Tissue Normal), aliquot TCGA-CZ-4863-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91355540-592a-4372-a8b1-6ca8f9c110a6

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Frame Shift Del 8, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4862C>G p.S1621* | Nonsense Mutation (SNP) | VAF 14/278 reads (5%) | catalogued as COSV101330187; called by muse, mutect2
- ADAMTS16 | c.2620T>A p.W874R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56980201; called by muse, mutect2, varscan2
- AHNAK | c.5157G>T p.K1719N | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57205199; called by muse, mutect2, varscan2
- ATP1A1 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55189949; called by muse, mutect2, varscan2
- C6orf62 | c.99del p.M34Cfs*26 | Frame Shift Del (DEL) | VAF 44/304 reads (14%) | catalogued as COSV65291138; called by mutect2, pindel, varscan2
- CEP152 | c.2913C>G p.I971M | Missense Mutation (SNP) | VAF 92/548 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV57857306; called by muse, mutect2, varscan2
- CTSH | c.398A>T p.K133I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV54984268; called by muse, mutect2, varscan2
- FAM180A | c.58T>A p.C20S | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV58527941; called by muse, mutect2, varscan2
- FAM180A | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV58527948; called by muse, mutect2, varscan2
- GLB1L | c.1913T>C p.L638P | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV55475581; called by muse, mutect2, varscan2
- GLG1 | c.1415A>T p.E472V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.499); catalogued as COSV52664287; called by muse, mutect2, varscan2
- IQCF2 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60761162; called by muse, varscan2
- KIAA1549L | c.4543A>G p.T1515A (on ENST00000321505; = p.T1812A on NM_012194.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100382458; called by muse, varscan2
- KLHL5 | c.976C>G p.R326G | Missense Mutation (SNP) | VAF 70/396 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV54671389, COSV54672017; called by muse, mutect2, varscan2
- MGA | c.7187del p.R2396Qfs*8 (on ENST00000219905 / NM_001164273.1; = p.R2187Qfs*8 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 28/226 reads (12%) | catalogued as COSV54962338; called by mutect2, pindel, varscan2
- MTMR4 | c.2114T>A p.L705H | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.797); catalogued as COSV60199516; called by muse, mutect2, varscan2
- NOM1 | c.2394T>G p.S798R | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.093); catalogued as COSV51979032; called by muse, mutect2, varscan2
- NOX1 | c.956T>A p.M319K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54193550; called by muse, varscan2
- ORC1 | c.1769A>G p.Q590R | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV65363394; called by muse, mutect2, varscan2
- PFKFB3 | c.1381A>T p.S461C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | PolyPhen benign (0.019); catalogued as COSV57987131; called by muse, mutect2, varscan2
- PKN2 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.952); catalogued as rs775227507, COSV60130154; called by muse, mutect2, varscan2
- SLC17A9 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV100948004; called by muse, mutect2, varscan2
- SLC19A2 | c.1256del p.R419Pfs*4 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as COSV52548369; called by mutect2, pindel, varscan2
- TMEM198 | c.801T>G p.D267E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54713686; called by muse, varscan2
- TNR | c.1822A>G p.T608A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54873037; called by muse, mutect2, varscan2
- TRUB2 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV55956470; called by muse, mutect2
- DDX11 | c.242_254del p.T81Mfs*46 | Frame Shift Del (DEL) | VAF 24/219 reads (11%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1734_1740del p.K578Nfs*47 | Frame Shift Del (DEL) | VAF 14/131 reads (11%) | called by mutect2, pindel
- LY75 | c.2154del p.S719Afs*59 | Frame Shift Del (DEL) | VAF 34/224 reads (15%) | called by mutect2, pindel, varscan2
- NR1I3 | c.49del p.Q17Kfs*10 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, pindel
- SLC39A10 | c.240del p.F80Lfs*7 | Frame Shift Del (DEL) | VAF 32/190 reads (17%) | called by mutect2, pindel, varscan2
- ABRAXAS2 | c.1128T>C p.D376= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV53716175; called by muse, mutect2, varscan2
- CRTC1 | c.265C>T p.L89= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV58716790; called by muse, mutect2, varscan2
- DMXL1 | c.5085A>G p.E1695= | Silent (SNP) | VAF 34/294 reads (12%) | catalogued as rs1193292325, COSV60705699; called by muse, mutect2, varscan2
- ENPP5 | c.876T>C p.N292= | Silent (SNP) | VAF 68/404 reads (17%) | catalogued as COSV57908190; called by muse, mutect2, varscan2
- FAT1 | c.1701T>G p.P567= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV71672209; called by muse, mutect2
- INTS13 | c.840T>C p.D280= | Silent (SNP) | VAF 68/441 reads (15%) | catalogued as COSV53901392; called by muse, mutect2
- MUC16 | c.35082T>C p.P11694= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as COSV67448431; called by muse, mutect2, varscan2
- SLC38A8 | c.897G>T p.R299= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV55305015; called by muse, mutect2, varscan2
- SUCLG1 | c.660G>A p.Q220= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV67264785; called by muse, mutect2, varscan2
- TNNI3K | c.2169C>G p.L723= | Silent (SNP) | VAF 34/221 reads (15%) | catalogued as COSV53946062; called by muse, mutect2, varscan2
- XIRP2 | c.-28G>C | 5'UTR (SNP) | VAF 34/179 reads (19%) | catalogued as COSV54685327; called by muse, mutect2, varscan2
